Somatic mutation profile of tumor specimen ALCH-B4DB-TTP1-A (aliquot ALCH-B4DB-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4DB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,780 days).
Specimen ALCH-B4DB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d62a09a2-b5b7-4b34-9d18-1eff04b03d14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4DB-NB1-A (Blood Derived Normal), aliquot ALCH-B4DB-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4f9a1e5-e818-49d1-8f32-18cd2b59d8bb

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Intron 3, Splice Site 3, Frame Shift Del 2, RNA 2, Nonsense Mutation 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 38/230 reads (17%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- CFAP47 | c.8504T>C p.M2835T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1012343186; called by muse, mutect2
- CLCN6 | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs201373379; called by muse, mutect2, varscan2
- CPS1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs150314086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMR1NB | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as COSV63272765; called by muse, mutect2, varscan2
- MUC16 | c.23966C>A p.T7989K | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV67480737, COSV67489321; called by muse, mutect2, varscan2
- NEXN | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD097742; called by muse, mutect2, varscan2
- NSD1 | c.7362G>C p.L2454F | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); catalogued as rs777005830; called by muse, mutect2, varscan2
- NUF2 | c.467del p.N156Tfs*8 | Frame Shift Del (DEL) | VAF 102/408 reads (25%) | catalogued as COSV54845361; called by pindel, varscan2
- RBM45 | c.1292A>G p.Y431C (on ENST00000616198 / NM_001365579.1; = p.Y429C on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774286990; called by muse, mutect2, varscan2
- SEMA5A | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs139668453; called by muse, mutect2, varscan2
- SERPINI2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs968036008; called by muse, mutect2, varscan2
- SPTA1 | c.6386G>C p.R2129T | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV63749351; called by muse, mutect2, varscan2
- TBL1X | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99483102; called by muse, mutect2
- THAP1 | c.354A>C p.L118F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.55); catalogued as rs1017616432, COSV54273437; called by muse, mutect2, varscan2
- VPS35 | c.1713G>T p.L571F | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV100140729, COSV54481187; called by muse, mutect2, varscan2
- ACE2 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP11A | c.3180G>T p.Q1060H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- C6orf118 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCSER1 | c.409del p.R137Gfs*13 | Frame Shift Del (DEL) | VAF 56/275 reads (20%) | called by mutect2, pindel, varscan2
- CHD4 | c.5692-7_5692-5del | Splice Region (DEL) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GFRAL | c.621C>A p.S207R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IQCG | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KATNIP | c.4701C>A p.H1567Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LUZP4 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.196); called by muse, mutect2
- MED12 | c.6115C>T p.Q2039* | Nonsense Mutation (SNP) | VAF 38/160 reads (24%) | called by muse, varscan2
- MTBP | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- MYO1A | c.2468T>C p.L823P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NODAL | c.28+1G>A p.X10_splice | Splice Site (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- PRDM1 | c.42+1G>T p.X14_splice | Splice Site (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- SARM1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); called by muse, varscan2
- SCN4A | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO4C1 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SLX4IP | c.507-1G>T p.X169_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- STRBP | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2
- TENM1 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMPRSS11B | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UCN | c.352A>T p.I118L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- WNK3 | c.4483C>T p.Q1495* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- ZFP92 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF729 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ALDH3A2 | c.1218G>A p.G406= | Silent (SNP) | VAF 65/257 reads (25%) | catalogued as rs1005715793, COSV51568739; called by muse, mutect2, varscan2
- CCDC74A | c.564C>A p.P188= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, varscan2
- CDH23 | c.2115C>T p.G705= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV54936384; called by muse, mutect2
- CLASP1 | c.1701G>C p.L567= | Silent (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- CLCN1 | c.513C>T p.L171= | Silent (SNP) | VAF 62/253 reads (25%) | catalogued as rs371546457; called by muse, mutect2, varscan2
- DCAF12L1 | c.1164C>T p.S388= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1218461875, COSV64422005; called by muse, mutect2, varscan2
- DSG3 | c.2814G>T p.S938= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV57126101, COSV57126699; called by muse, mutect2, varscan2
- GABRA4 | c.42C>T p.A14= | Silent (SNP) | VAF 43/205 reads (21%) | catalogued as rs1367938149; called by muse, mutect2, varscan2
- IGDCC4 | c.321A>T p.S107= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- MVB12A | c.369G>T p.R123= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- TBC1D2 | c.2157G>T p.A719= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV59785853; called by muse, mutect2, varscan2
- ALDOB | c.-10-15C>T | Intron (SNP) | VAF 46/224 reads (21%) | catalogued as rs771433487; called by muse, mutect2, varscan2
- OR2W5 | n.1047C>A | RNA (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- RPSAP52 | n.788A>G | RNA (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- SSX2IP | c.1389+260del | Intron (DEL) | VAF 47/186 reads (25%) | called by mutect2, pindel, varscan2
- UBE2I | c.413+108del | Intron (DEL) | VAF 4/31 reads (13%) | catalogued as rs758341579; called by mutect2, varscan2
